Gene-level copy-number profile of tumor specimen TCGA-KD-A5QT-01A from TCGA case TCGA-KD-A5QT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 69.1 years (25,249 days).
Specimen TCGA-KD-A5QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.fc168f3e-34b0-42cd-97f5-5a5bce21ee34.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KD-A5QT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8005d98d-770b-40de-aa6f-1f5fef1556b0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 175; copy number 1: 8,358; copy number 2: 46,514; copy number 3: 4,634; copy number 4: 110; copy number 5: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KD-A5QT-01A-11D-A27O-01): tumor purity 0.96, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 175 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:108,166,022–109,174,418, 30 genes (within-gene range 0–1): NR2E1, AL078596.1, SNX3, Z98742.2, RNA5SP212, Z98742.4, Z98742.1, RNU6-1144P, AFG1L, Z98742.3, AL356121.2, AL356121.1, AL353706.1, RNU6-770P, AL139106.1, AL391646.1, FOXO3, SUMO2P8, LINC00222, ZNF259P1, Z95118.2, Z95118.1, ARMC2, AL445189.1, ATP5MFP2, ARMC2-AS1, SESN1, AL390208.1, RNU6-653P, CEP57L1.
- chr13:34,262,863–34,263,090, 1 gene: AL356321.1.
- chr13:48,296,162–51,200,252, 68 genes (within-gene range 0–1) (broad region; genes not listed).
- chr13:54,115,783–55,174,548, 10 genes: LINC00458, AL356052.1, MIR1297, RPL13AP25, AL442636.1, AL512655.1, AL390964.1, LINC02335, AL139038.1, MIR5007.
- chr13:58,527,655–59,263,391, 7 genes: RNY4P29, CTAGE16P, DNAJA1P1, HMGN2P39, POLR3KP1, AL159156.1, RPP40P2.
- chr13:59,665,583–64,076,044, 44 genes (within-gene range 0–3): DIAPH3, DIAPH3-AS1, RN7SL375P, DIAPH3-AS2, RNY4P28, LINC00434, TARDBPP2, AL359920.1, TDRD3, RNA5SP31, LINC00378, EIF4A1P6, AL161901.1, RNY3P5, LINC01442, MIR3169, PCDH20, AL592490.1, LINC02339, RAC1P8, AL353765.1, LINC00358, LINC01075, LINC01074, LINC00459, RPL32P28, AL356102.1, SQSTM1P1, AL445668.1, LINC00448, AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr13:76,552,807–77,129,717, 14 genes: AL136441.1, AL161717.1, AL365394.1, KCTD12, AC000403.1, BTF3P11, ACOD1, RPL7P44, DHX9P1, CLN5, AC001226.2, FBXL3, MYCBP2-AS1, AC001226.1.
- chr13:77,080,511–77,081,190, 1 gene: MYCBP2-AS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:157,539,056–158,587,823, 10 genes, copy number 5 (within-gene range 1–5): PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1.

Autosomal genes at a single copy (total copy number 1): 8,115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
